Somatic mutation profile of tumor specimen TCGA-AK-3443-01A (aliquot TCGA-AK-3443-01A-01W-0886-08) from TCGA case TCGA-AK-3443, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: GX; Age at diagnosis: 45.4 years (16,578 days).
Specimen TCGA-AK-3443-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61f35099-aae4-4a49-a686-e0ba53d84c14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AK-3443-10A (Blood Derived Normal), aliquot TCGA-AK-3443-10A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/456e017a-af04-4529-abe1-8b6780e4bc74

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Frame Shift Ins 3, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANTXR2 | c.1073dup p.A359Cfs*13 | Frame Shift Ins (INS) | VAF 4/29 reads (14%) | catalogued as rs312262690; ClinVar: pathogenic; called by pindel, varscan2
- BMP10 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.094); catalogued as rs141935259; called by muse, mutect2, varscan2
- SOS2 | c.1373A>G p.H458R | Missense Mutation (SNP) | VAF 101/261 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.056); catalogued as rs766792092; called by muse, mutect2, varscan2
- SSH2 | c.2756dup p.E920Rfs*22 | Frame Shift Ins (INS) | VAF 44/381 reads (12%) | catalogued as rs752567808; called by mutect2, varscan2
- CKAP2L | c.1760C>T p.P587L | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FREM2 | c.218T>A p.V73E | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, varscan2
- HS3ST2 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- KIAA0513 | c.741dup p.L248Afs*66 | Frame Shift Ins (INS) | VAF 6/34 reads (18%) | called by pindel, varscan2
- MTMR3 | c.228A>G p.I76M | Missense Mutation (SNP) | VAF 60/136 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- PCDHB3 | c.2360C>A p.P787H | Missense Mutation (SNP) | VAF 8/151 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.019); called by muse, mutect2
- AQR | c.471+913T>C | Intron (SNP) | VAF 39/74 reads (53%) | called by muse, mutect2, varscan2
- SPEG | c.389-1514G>A | Intron (SNP) | VAF 168/378 reads (44%) | catalogued as rs1228606232; called by muse, mutect2, varscan2
